Gene-level copy-number profile of tumor specimen TCGA-EB-A3XC-01A from TCGA case TCGA-EB-A3XC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 74.3 years (27,124 days).
Specimen TCGA-EB-A3XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.badc4356-3544-4162-b4e8-88b15e3b4205.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A3XC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f8134e92-1188-4fa0-9683-85cd550a30de

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 117; copy number 1: 224; copy number 2: 13,270; copy number 3: 15,451; copy number 4: 24,156; copy number 5: 1,490; copy number 6: 2,068; copy number 7: 450; copy number 8: 2,345; copy number 9: 243.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A3XC-01A-11D-A238-01): tumor purity 0.61, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 117 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:16,409,503–16,870,843, 1 gene (within-gene range 0–1): BNC2.
- chr9:16,625,676–17,114,122, 6 genes (within-gene range 0–2): AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P.
- chr9:20,999,509–24,592,104, 73 genes (broad region; genes not listed).
- chr9:25,088,811–25,584,272, 2 genes: RN7SKP120, AL353730.1.
- chr9:26,066,675–28,888,955, 33 genes: AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr9:29,317,833–29,636,853, 2 genes: AL353684.1, AL354676.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 243 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:77,122,434–97,740,472, 243 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
